Somatic mutation profile of tumor specimen TCGA-AG-A036-01A (aliquot TCGA-AG-A036-01A-12W-A096-10) from TCGA case TCGA-AG-A036, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.7 years (26,206 days).
Specimen TCGA-AG-A036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7800bfb7-e531-460c-a67e-c0e993846091.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A036-11A (Solid Tissue Normal), aliquot TCGA-AG-A036-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86eea021-1fbd-40db-b0b3-a42adf6a4b06

The open-access MAF lists 191 somatic variants for this specimen: 138 protein-altering or splice-affecting, 48 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 48, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 2, RNA 2, In Frame Del 1, Intron 1, Frame Shift Ins 1, Nonstop Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 81/328 reads (25%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 159/536 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 153/259 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1930C>G p.L644V | Missense Mutation (SNP) | VAF 65/663 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99710723; called by muse, mutect2, varscan2
- ADAMTS16 | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs780954477, COSV99941808; called by muse, mutect2, varscan2
- AFF3 | c.2760C>A p.D920E | Missense Mutation (SNP) | VAF 54/551 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100419375; called by muse, mutect2
- ANO1 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60283419; called by muse, varscan2
- ATAD2B | c.2939T>G p.F980C | Missense Mutation (SNP) | VAF 32/541 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53197393; called by muse, mutect2
- BTBD7 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100108070; called by muse, mutect2
- C11orf87 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1413462079, COSV59356112, COSV59357138; called by muse, mutect2, varscan2
- C2orf15 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.164); catalogued as COSV56781730; called by muse, mutect2, varscan2
- CAMSAP1 | c.4496C>A p.S1499Y | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100410090; called by muse, mutect2
- CDCA3 | c.748T>C p.W250R | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV99976991; called by muse, mutect2, varscan2
- CDH19 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.133); catalogued as COSV50957183; called by muse, mutect2, varscan2
- CDON | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1356704055, COSV54997042; called by muse, mutect2, varscan2
- CHN1 | c.570A>T p.R190S | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.573); catalogued as COSV55032945; called by muse, mutect2
- CLIC2 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 184/313 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV58936246; called by muse, mutect2, varscan2
- CNIH4 | c.251+1G>C p.X84_splice | Splice Site (SNP) | VAF 194/784 reads (25%) | catalogued as COSV100837014; called by muse, mutect2, varscan2
- CNKSR3 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 80/883 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101401373; called by muse, mutect2
- CORIN | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 10/214 reads (5%) | catalogued as COSV56691660, COSV99903894; called by muse, mutect2
- CRADD | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs752845581, COSV60553100; called by muse, mutect2, varscan2
- DEPDC1 | c.2290C>A p.L764I (on ENST00000456315 / NM_001114120.3; = p.L480I on NM_017779.6) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV63958063; called by muse, mutect2, varscan2
- DNAH7 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 38/453 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as COSV100415983; called by muse, mutect2
- DNAH9 | c.6041T>C p.I2014T | Missense Mutation (SNP) | VAF 55/525 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs751263153, COSV52345234; called by muse, mutect2, varscan2
- E2F3 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60897078; called by muse, mutect2, varscan2
- EIF2B2 | c.196A>T p.R66W | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56720190; called by muse, mutect2, varscan2
- EIPR1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66129206; called by muse, mutect2, varscan2
- EP300 | c.5457G>T p.Q1819H | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99609039; called by muse, mutect2
- EPG5 | c.3686C>A p.P1229H | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs778094374, COSV99957582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA6 | c.3101T>G p.L1034R | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67568708; called by muse, mutect2
- EPHA8 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs373378884, COSV99385162; called by muse, mutect2, varscan2
- EPYC | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 98/867 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99664717; called by muse, mutect2, varscan2
- EXOC6B | c.1160C>G p.T387S | Missense Mutation (SNP) | VAF 53/1042 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV55551881; called by muse, mutect2
- FAT3 | c.8572C>T p.Q2858* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV53099513; called by muse, mutect2, varscan2
- FER1L6 | c.1705T>C p.Y569H | Missense Mutation (SNP) | VAF 72/1092 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV67549192; called by muse, mutect2
- FGF12 | c.599C>T p.P200L (on ENST00000454309 / NM_021032.5; = p.P138L on NM_004113.6) | Missense Mutation (SNP) | VAF 208/453 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306846680, COSV53160950; called by muse, varscan2
- FHL5 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780594540, COSV58735060; called by muse, mutect2, varscan2
- FNDC1 | c.5496C>G p.C1832W | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99796157; called by muse, mutect2, varscan2
- GALNTL5 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV67179902; called by muse, mutect2, varscan2
- GCAT | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50648865; called by muse, mutect2, varscan2
- GLI3 | c.4311G>T p.Q1437H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV101229932; called by muse, mutect2, varscan2
- GLIPR1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs760375651, COSV56990545; called by muse, mutect2, varscan2
- GRIA4 | c.2534A>C p.K845T | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV99232592; called by muse, mutect2, varscan2
- H6PD | c.575C>G p.T192S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101072510, COSV66230839; called by muse, mutect2, varscan2
- HECW1 | c.601A>C p.S201R | Missense Mutation (SNP) | VAF 68/793 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV101223911; called by muse, mutect2
- HEY1 | c.915A>C p.*305Yext*6 | Nonstop Mutation (SNP) | VAF 28/166 reads (17%) | catalogued as COSV61232794; called by mutect2, varscan2
- HMMR | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62373928, COSV62374318; called by muse, mutect2
- HNRNPH1 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV61485452; called by muse, mutect2, varscan2
- IVL | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100908196; called by muse, mutect2, varscan2
- KCNH6 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs771454089, COSV59004928; called by muse, mutect2, varscan2
- KDM1B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV99924395; called by muse, mutect2
- KDM4A | c.430-1G>A p.X144_splice | Splice Site (SNP) | VAF 56/267 reads (21%) | catalogued as COSV100969543; called by muse, mutect2, varscan2
- KDM5A | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs778494527, COSV66991330; called by muse, mutect2, varscan2
- KL | c.2235C>A p.D745E | Missense Mutation (SNP) | VAF 30/337 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV101199125; called by muse, mutect2
- KMT2C | c.11035G>A p.E3679K | Missense Mutation (SNP) | VAF 95/684 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV51434327; called by muse, mutect2, varscan2
- KRT32 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV56786383; called by muse, mutect2, varscan2
- KRT82 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs750740979, COSV57787464; called by muse, mutect2, varscan2
- LMNTD1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV51446201; called by muse, mutect2, varscan2
- LRCH2 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV100407068; called by muse, mutect2
- LRIF1 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 91/549 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778528380, COSV100870869; called by muse, mutect2, varscan2
- LRP1B | c.6591A>C p.L2197F | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257964; called by muse, mutect2, varscan2
- LRRC14B | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs760923609, COSV57256563; called by muse, mutect2, varscan2
- MARVELD2 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs746116082, COSV100347419, COSV57782201; called by muse, varscan2
- MBD5 | c.1621T>A p.F541I | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101290142; called by muse, mutect2, varscan2
- MMD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as rs916914975, COSV101287059; called by muse, mutect2
- MSANTD4 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 225/640 reads (35%) | catalogued as COSV57285506; called by muse, mutect2, varscan2
- MUC16 | c.5158A>C p.S1720R | Missense Mutation (SNP) | VAF 92/617 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101200328; called by muse, mutect2, varscan2
- MYO3A | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779068, COSV99780341; called by muse, mutect2
- NALCN | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51918402, COSV99216118; called by muse, mutect2, varscan2
- NBEAL2 | c.3143T>A p.I1048K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99436506; called by muse, mutect2, varscan2
- NCAPG | c.1677A>T p.K559N | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52269611; called by muse, mutect2, varscan2
- NCKAP1L | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 119/921 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.616); catalogued as COSV53207422; called by muse, mutect2, varscan2
- NELL1 | c.997+1G>A p.X333_splice | Splice Site (SNP) | VAF 282/520 reads (54%) | catalogued as rs1445980849, COSV54267982; called by muse, mutect2, varscan2
- NFKBIZ | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV100397112; called by muse, mutect2, varscan2
- NGF | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV65687483, COSV65688961; called by muse, mutect2, varscan2
- NPC1L1 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56924195; called by muse, mutect2
- OR1L6 | c.562A>T p.I188F (on ENST00000373684; = p.I152F on NM_001004453.2) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.902); catalogued as COSV59028321; called by muse, mutect2, varscan2
- OR4D1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775008445, COSV99274199; called by muse, mutect2, varscan2
- OR51G2 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1364811587, COSV100432167; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.634A>G p.S212G (on ENST00000374531 / NM_001037293.2; = p.S244G on NM_053016.6) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100093273; called by muse, mutect2, varscan2
- PCDHGB2 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53930536; called by muse, mutect2, varscan2
- PHLPP1 | c.2110G>C p.G704R | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.944); catalogued as COSV53026743; called by muse, mutect2, varscan2
- PIGU | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs577900938, COSV54161950; called by muse, mutect2, varscan2
- PRDM15 | c.2799G>C p.K933N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54151275; called by muse, varscan2
- PRPF40A | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 104/853 reads (12%) | catalogued as COSV68356970; called by muse, mutect2, varscan2
- PTPRC | c.3275A>G p.D1092G | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100722804; called by muse, mutect2
- PTPRT | c.1661T>A p.V554E | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV100628465; called by muse, mutect2
- RAB14 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV53045927; called by muse, mutect2, varscan2
- RAD54L2 | c.4073C>T p.T1358M | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as rs139648304; called by muse, mutect2, varscan2
- RAG2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs189020262, COSV57559175; called by muse, mutect2
- RAN | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs11546492, COSV54562707; called by muse, mutect2, varscan2
- RASGRF1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1166184207, COSV69177458; called by muse, mutect2, varscan2
- RD3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as rs778700426, COSV65362777; called by muse, mutect2
- RDH10 | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 53/512 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs973578810, COSV53582015; called by muse, mutect2, varscan2
- RIF1 | c.6595A>C p.N2199H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99690774; called by muse, mutect2, varscan2
- RIMBP2 | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as COSV99899863; called by muse, mutect2, varscan2
- RIMS1 | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as COSV99328045; called by muse, mutect2
- RRP8 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as rs770567575, COSV99601954; called by muse, mutect2, varscan2
- RUNX1T1 | c.1117C>T p.R373* (on ENST00000265814 / NM_001198628.1; = p.R346* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/367 reads (12%) | catalogued as COSV56143680, COSV56151272; called by muse, mutect2, varscan2
- RYR2 | c.6931G>A p.E2311K | Missense Mutation (SNP) | VAF 215/629 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100771438; called by muse, mutect2, varscan2
- SASH1 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100821277, COSV66566728; called by muse, mutect2, varscan2
- SEC24A | c.1986G>C p.K662N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV59745804, COSV59746787; called by muse, mutect2, varscan2
- SGO2 | c.3336A>T p.Q1112H | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100764710; called by muse, mutect2, varscan2
- SHPRH | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574465156, COSV51604046, COSV99261771; called by muse, mutect2, varscan2
- SLC12A3 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99344409; called by muse, mutect2, varscan2
- SLC34A2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs759231403, COSV101158255, COSV65941183; called by muse, mutect2, varscan2
- SMAD3 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280608, COSV59281555, COSV59282880; called by muse, mutect2, varscan2
- SRMS | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760106125, COSV53916540; called by muse, mutect2, varscan2
- SULF1 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs746878657, COSV52679165; called by muse, mutect2, varscan2
- SYNE1 | c.16012T>A p.W5338R (on ENST00000367255 / NM_182961.4; = p.W5267R on NM_033071.3) | Missense Mutation (SNP) | VAF 57/597 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54958295; called by muse, mutect2
- TAF5L | c.1235C>G p.S412* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV51078558, COSV51079108; called by muse, mutect2, varscan2
- TEK | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.865); catalogued as rs1368043969, COSV66228589; called by muse, mutect2, varscan2
- TFCP2L1 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs768235839, COSV99748389; called by muse, mutect2, varscan2
- TFEC | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99624720; called by muse, mutect2
- THBS2 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs757104686, COSV64678844; called by muse, mutect2, varscan2
- THSD7B | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs546067581, COSV99753512; called by muse, mutect2, varscan2
- TNFRSF10B | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99375471; called by muse, mutect2, varscan2
- TNN | c.1862A>G p.D621G | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771337724, COSV99512299; called by muse, mutect2, varscan2
- TNR | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99690280; called by muse, mutect2, varscan2
- TPR | c.1578_1580del p.S530del | In Frame Del (DEL) | VAF 40/286 reads (14%) | catalogued as COSV66600795; called by mutect2, pindel, varscan2
- TRGV3 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 56/624 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs747554783; called by muse, mutect2
- TRPC7 | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 39/493 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100725799; called by muse, mutect2
- TTN | c.86539C>A p.P28847T (on ENST00000591111; = p.P21423T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/197 reads (10%) | PolyPhen benign (0.436); catalogued as COSV59994103; called by muse, mutect2, varscan2
- UBE4B | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV53530455; called by muse, mutect2, varscan2
- UNC13C | c.5024T>G p.L1675R | Missense Mutation (SNP) | VAF 63/500 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52863492; called by muse, mutect2, varscan2
- UNC45B | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745572525, COSV99268852; called by muse, mutect2, varscan2
- USP25 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99584053; called by muse, mutect2
- USP32 | c.3756G>C p.E1252D | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100342277; called by muse, mutect2, varscan2
- WAC | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV61567388; called by muse, mutect2, varscan2
- ZC3HC1 | c.1142G>C p.S381T | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100315880; called by muse, mutect2, varscan2
- ZNF285 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100450050; called by muse, mutect2, varscan2
- ZNF385A | c.437G>C p.G146A (on ENST00000338010 / NM_001130967.3; = p.G126A on NM_015481.3) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.646); catalogued as COSV100566977, COSV61493117; called by muse, mutect2, varscan2
- ZNF583 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV99382197; called by muse, mutect2, varscan2
- ZNF804B | c.2945_2946insC p.K982Nfs*7 | Frame Shift Ins (INS) | VAF 24/211 reads (11%) | catalogued as COSV100304553; called by mutect2, pindel, varscan2
- PPDPFL | c.83del p.L28* | Frame Shift Del (DEL) | VAF 68/388 reads (18%) | called by mutect2, pindel*, varscan2
- RUNX1 | c.483_489del p.Y162Efs*20 (on ENST00000344691 / NM_001001890.3; = p.Y189Efs*20 on NM_001754.5) | Frame Shift Del (DEL) | VAF 157/829 reads (19%) | called by mutect2, pindel, varscan2
- SNRNP48 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.135); called by muse, mutect2
- ABCA12 | c.5268C>G p.V1756= (on ENST00000272895 / NM_173076.3; = p.V1438= on NM_015657.3) | Silent (SNP) | VAF 22/428 reads (5%) | catalogued as COSV99790674; called by muse, mutect2
- ACTN4 | c.1383C>T p.S461= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs750702920, COSV53145085, COSV99400605; called by muse, mutect2, varscan2
- ADGRA1 | c.435C>A p.I145= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV66925372; called by muse, mutect2, varscan2
- AFF3 | c.3570C>T p.N1190= | Silent (SNP) | VAF 80/157 reads (51%) | catalogued as rs201311680, COSV57850766; called by muse, mutect2, varscan2
- ALDH1A2 | c.882T>C p.I294= | Silent (SNP) | VAF 57/311 reads (18%) | catalogued as COSV51079906; called by muse, mutect2, varscan2
- CHAF1B | c.396G>A p.V132= | Silent (SNP) | VAF 168/562 reads (30%) | catalogued as COSV58439793; called by muse, mutect2, varscan2
- CYP4B1 | c.1107C>T p.C369= | Silent (SNP) | VAF 44/222 reads (20%) | catalogued as COSV54722990; called by muse, mutect2, varscan2
- DHRS4 | c.21A>T p.L7= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV57480590; called by muse, mutect2, varscan2
- DPP10 | c.1767T>A p.I589= | Silent (SNP) | VAF 36/251 reads (14%) | catalogued as COSV59680287; called by muse, mutect2, varscan2
- EIF2B2 | c.195C>G p.G65= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV56720166; called by muse, mutect2, varscan2
- FBXO38 | c.1482C>A p.S494= | Silent (SNP) | VAF 69/556 reads (12%) | catalogued as COSV57027063; called by muse, mutect2, varscan2
- FEV | c.114C>T p.P38= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1356787537, COSV55386438; called by muse, mutect2, varscan2
- FH | c.1155C>T p.A385= | Silent (SNP) | VAF 28/239 reads (12%) | catalogued as COSV63817883; called by muse, mutect2, varscan2
- FMO3 | c.1023T>A p.S341= | Silent (SNP) | VAF 65/496 reads (13%) | catalogued as COSV63006957; called by muse, mutect2, varscan2
- GLUD2 | c.1065T>C p.H355= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV60151735, COSV60151807; called by muse, mutect2, varscan2
- GSE1 | c.1371G>A p.P457= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs371123194; called by muse, mutect2, varscan2
- IKZF3 | c.1380C>T p.L460= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV53100028; called by muse, mutect2
- KCNJ6 | c.762G>A p.P254= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs373930118; called by muse, mutect2, varscan2
- MARCHF4 | c.432C>T p.T144= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs374936017, COSV56104490; called by muse, mutect2, varscan2
- MTMR4 | c.3510C>T p.Y1170= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs143878413; called by muse, mutect2, varscan2
- MUC5B | c.14178C>A p.S4726= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV71591354; called by muse, mutect2, varscan2
- MYO3A | c.1533G>T p.L511= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV56349385; called by muse, mutect2
- OR4K1 | c.669C>T p.I223= | Silent (SNP) | VAF 77/481 reads (16%) | catalogued as rs141997601, COSV53459749; called by muse, mutect2, varscan2
- PCDHB8 | c.1344C>T p.N448= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1554281186, COSV50753525; called by muse, mutect2, varscan2
- PCDHGA6 | c.2094C>T p.A698= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99541363; called by muse, varscan2
- PIK3R4 | c.3144C>G p.L1048= | Silent (SNP) | VAF 102/510 reads (20%) | catalogued as COSV63240160, COSV63242375; called by muse, mutect2, varscan2
- PPP1R9A | c.2802A>C p.S934= | Silent (SNP) | VAF 38/380 reads (10%) | catalogued as COSV99196271; called by muse, mutect2, varscan2
- PYROXD1 | c.63G>C p.A21= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs757345717, COSV53709200; called by muse, mutect2, varscan2
- RALGAPB | c.1113T>G p.P371= | Silent (SNP) | VAF 186/1078 reads (17%) | catalogued as COSV99485416; called by muse, varscan2
- RB1 | c.372A>C p.I124= | Silent (SNP) | VAF 18/378 reads (5%) | catalogued as COSV99925474; called by muse, mutect2
- RB1CC1 | c.3222A>T p.I1074= | Silent (SNP) | VAF 34/450 reads (8%) | catalogued as COSV99212408; called by muse, mutect2
- SARDH | c.2637G>A p.S879= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs775373624, COSV64099271; called by muse, mutect2, varscan2
- SBNO1 | c.1062C>T p.D354= (on ENST00000420886; = p.D353= on NM_018183.5) | Silent (SNP) | VAF 65/353 reads (18%) | catalogued as COSV57340748; called by muse, mutect2, varscan2
- SCAI | c.1090C>T p.L364= (on ENST00000336505 / NM_001144877.3; = p.L387= on NM_173690.5) | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as COSV60611984; called by muse, mutect2
- SCN10A | c.306C>A p.S102= | Silent (SNP) | VAF 56/440 reads (13%) | catalogued as COSV71860990; called by muse, varscan2
- SCN2B | c.495C>T p.S165= | Silent (SNP) | VAF 45/305 reads (15%) | catalogued as rs1217452578, COSV54050430; called by muse, mutect2, varscan2
- SH2D3C | c.381C>T p.A127= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV100137133; called by muse, mutect2, varscan2
- SLC4A3 | c.513C>T p.D171= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs757698492, COSV56092984; called by muse, mutect2, varscan2
- SPTY2D1 | c.1455G>A p.P485= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs558612480, COSV60473579; called by muse, mutect2, varscan2
- STX4 | c.858C>T p.L286= | Silent (SNP) | VAF 32/282 reads (11%) | catalogued as COSV58268218; called by muse, mutect2, varscan2
- TBC1D12 | c.1509T>C p.N503= | Silent (SNP) | VAF 144/463 reads (31%) | catalogued as COSV56553611; called by muse, mutect2, varscan2
- TRPS1 | c.48C>T p.G16= (on ENST00000220888 / NM_001330599.2; = p.G29= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/218 reads (44%) | catalogued as rs757105545, COSV55235955; called by muse, mutect2, varscan2
- TTN | c.81144A>G p.E27048= (on ENST00000591111; = p.E19624= on NM_003319.4) | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV59994109; called by muse, mutect2, varscan2
- UPK1A | c.444C>T p.R148= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as rs760111506, COSV55877976; called by muse, mutect2, varscan2
- URI1 | c.1056G>A p.K352= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV100369203, COSV56349330; called by muse, mutect2, varscan2
- XIRP2 | c.1810T>C p.L604= (on ENST00000628543; = p.L779= on NM_152381.6) | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV54694195, COSV99742044; called by muse, mutect2, varscan2
- ZNF280C | c.813T>A p.I271= | Silent (SNP) | VAF 110/165 reads (67%) | catalogued as COSV63968803; called by muse, mutect2, varscan2
- ZNF7 | c.816C>T p.H272= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV57383321; called by muse, mutect2, varscan2
- MIR421 | n.19T>G | RNA (SNP) | VAF 191/299 reads (64%) | called by muse, mutect2, varscan2
- MIR892A | n.61C>T | RNA (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- SIGLECL1 | c.*2C>G | 3'UTR (SNP) | VAF 105/347 reads (30%) | catalogued as COSV100323965; called by muse, mutect2, varscan2
- TMTC4 | c.-42C>G | 5'UTR (SNP) | VAF 88/182 reads (48%) | catalogued as COSV60891930; called by muse, mutect2, varscan2
- TTN | c.10303+2536G>A | Intron (SNP) | VAF 17/139 reads (12%) | catalogued as rs566456478, COSV100619135; called by muse, mutect2, varscan2
